Gene-level copy-number profile of tumor specimen HTMCP-03-06-02040-01A from CGCI case HTMCP-03-06-02040, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 65.1 years (23,795 days).
Specimen HTMCP-03-06-02040-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file de3cbd77-822b-4c86-80e8-9be54ca8b324.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02040-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/3e4f5a77-8b3d-4162-aab1-77f37089e3ce

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 8; copy number 2: 8,131; copy number 3: 19,967; copy number 4: 16,153; copy number 5: 9,736; copy number 6: 3,750; copy number 7: 560; copy number 8: 32; copy number 9: 17; copy number 10: 2; copy number 12: 1; copy number 16: 8.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr2:132,037,787–132,037,993, 1 gene: AC093787.1.
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.
- chr8:7,715,443–7,795,870, 10 genes: FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P.
- chr8:7,926,337–8,049,267, 12 genes (within-gene range 0–2): ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1.
- chr16:78,355,529–78,355,834, 1 gene (within-gene range 0–3): LSM3P5.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 620 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–36,725,195, 542 genes, copy number 7–8 (within-gene range 7–9) (broad region; genes not listed).
- chr7:38,239,580–38,335,514, 16 genes, copy number 9: TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr7:142,670,740–142,793,368, 21 genes, copy number 7: TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr7:142,801,041–142,802,748, 1 gene, copy number 7: TRBC2.
- chr8:7,238,286–7,247,571, 2 genes, copy number 10: AF228730.3, OR7E125P.
- chr8:7,295,014–7,298,024, 1 gene, copy number 9: FAM90A20P.
- chr8:7,355,517–7,385,558, 2 genes, copy number 7: ZNF705G, DEFB108C.
- chr9:60,914,407–61,666,386, 17 genes, copy number 8: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr9:63,581,254–63,776,143, 8 genes, copy number 7: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3.
- chr13:74,434,538–74,555,515, 1 gene, copy number 12 (within-gene range 5–12): AL355390.2.
- chr16:32,715,931–32,788,944, 8 genes, copy number 16: AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr20:23,980,585–23,980,734, 1 gene, copy number 7: AL133466.1.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
